Somatic mutation profile of tumor specimen TCGA-VQ-A91Z-01A (aliquot TCGA-VQ-A91Z-01A-11D-A410-08) from TCGA case TCGA-VQ-A91Z, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.5 years (24,652 days).
Specimen TCGA-VQ-A91Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 327d6422-77ca-4f4d-bf3d-61ff959d226a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91Z-10A (Blood Derived Normal), aliquot TCGA-VQ-A91Z-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4438bbd6-df22-4a03-8546-2b8c9a5656e3

The open-access MAF lists 161 somatic variants for this specimen: 121 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 36, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 4, RNA 2, 3'UTR 1, Nonstop Mutation 1, Splice Region 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTS | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs765406631, CM951090, COSV99737855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 19/24 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6875A>C p.N2292T (on ENST00000272895 / NM_173076.3; = p.N1974T on NM_015657.3) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789403; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1037C>G p.P346R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99647034; called by muse, mutect2, varscan2
- ADGRG4 | c.3079G>T p.E1027* | Nonsense Mutation (SNP) | VAF 61/167 reads (37%) | catalogued as COSV99795151; called by muse, mutect2, varscan2
- AKAP9 | c.5723_5726del p.T1908Sfs*2 (on ENST00000359028; = p.T1876Sfs*2 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/85 reads (35%) | catalogued as rs755378911; called by pindel, varscan2
- AKAP9 | c.6364C>A p.L2122I (on ENST00000359028; = p.L2090I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100662244; called by muse, mutect2, varscan2
- ANK1 | c.4306C>T p.R1436* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as CM960065, COSV55878288; called by muse, mutect2, varscan2
- AOAH | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV99332517; called by muse, mutect2, varscan2
- ATE1 | c.1526G>A p.C509Y | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99816950; called by muse, mutect2, varscan2
- ATP13A5 | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as rs753509516, COSV60877842; called by muse, mutect2, varscan2
- BRIP1 | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99369825; called by muse, mutect2, varscan2
- CACNA1B | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99496607; called by muse, mutect2, varscan2
- CACNA1H | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs376566207; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN7 | c.1241G>T p.S414I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV99512713; called by muse, mutect2, varscan2
- CCDC191 | c.1996A>G p.I666V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99878116; called by muse, mutect2, varscan2
- CCDC9B | c.389G>C p.W130S | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101233501; called by muse, mutect2, varscan2
- CD1C | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100939378, COSV63807289; called by muse, mutect2, varscan2
- CD93 | c.943dup p.A315Gfs*34 | Frame Shift Ins (INS) | VAF 28/111 reads (25%) | catalogued as rs747115137; called by mutect2, varscan2
- CDH23 | c.7723G>A p.E2575K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs762925264, COSV99820244; called by muse, varscan2
- CFAP299 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100811530; called by muse, mutect2, varscan2
- CGN | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV99642173; called by muse, mutect2, varscan2
- CHST12 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs905098497, COSV51676142; called by muse, mutect2, varscan2
- CLEC14A | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100643464; called by muse, mutect2, varscan2
- CLSTN2 | c.428+1G>T p.X143_splice | Splice Site (SNP) | VAF 41/87 reads (47%) | catalogued as COSV101515651, COSV71721652, COSV71724835; called by muse, mutect2, varscan2
- CNTN6 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100610485; called by muse, mutect2, varscan2
- COL5A1 | c.2899-1G>A p.X967_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as CS128988, COSV100879763, COSV65673592; called by muse, mutect2, varscan2
- CPED1 | c.2056-1G>A p.X686_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as rs1349297351, COSV60002683; called by muse, mutect2, varscan2
- CRISP2 | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 25/98 reads (26%) | catalogued as rs147611117; called by muse, mutect2, varscan2
- CSRNP3 | c.1512C>A p.C504* | Nonsense Mutation (SNP) | VAF 26/48 reads (54%) | catalogued as COSV100085513; called by muse, mutect2, varscan2
- CYC1 | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100010331; called by muse, mutect2, varscan2
- CYP2D6 | c.991G>T p.V331F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637281; called by muse, mutect2, varscan2
- DHPS | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1444144482, COSV99269574; called by muse, mutect2, varscan2
- DNAH7 | c.9121G>A p.E3041K | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753140811, COSV56774194; called by muse, mutect2, varscan2
- DPP6 | c.1580G>A p.C527Y (on ENST00000377770 / NM_001364500.2; = p.C465Y on NM_001936.5) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100124544; called by muse, mutect2, varscan2
- DVL3 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1266047392, COSV100493595; called by muse, mutect2, varscan2
- EHBP1 | c.2185G>A p.G729S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1244788136, COSV99860580; called by muse, mutect2, varscan2
- ERH | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV99384004; called by muse, mutect2, varscan2
- ERVW-1 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs1471371734, COSV71259332; called by muse, varscan2
- EYA4 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV100765581; called by muse, mutect2, varscan2
- FAT2 | c.8194C>G p.P2732A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as COSV55821699; called by muse, mutect2, varscan2
- FGF10 | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99240410; called by muse, mutect2, varscan2
- FLG | c.3490A>C p.T1164P | Missense Mutation (SNP) | VAF 96/396 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV64237791; called by muse, mutect2, varscan2
- FLG2 | c.2629A>C p.S877R | Missense Mutation (SNP) | VAF 211/381 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101165778, COSV66167293; called by muse, mutect2, varscan2
- FRMD6 | c.1330G>A p.D444N (on ENST00000344768 / NM_001267046.2; = p.D436N on NM_152330.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100655708; called by muse, mutect2, varscan2
- GLIS3 | c.1729C>A p.H577N | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as rs1563806220, COSV100173740; called by muse, mutect2, varscan2
- GRM2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99622693; called by muse, mutect2, varscan2
- HDX | c.1596A>C p.E532D | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1323911168, COSV52978701; called by muse, mutect2, varscan2
- IGSF6 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99193623; called by muse, mutect2, varscan2
- KIF19 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs771816123, COSV63429663; called by muse, mutect2, varscan2
- KIRREL1 | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230153173, COSV100779703; called by muse, mutect2, varscan2
- KLHL18 | c.968C>A p.T323K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99230743; called by muse, mutect2, varscan2
- KLHL4 | c.23A>C p.E8A | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV100909412; called by muse, mutect2, varscan2
- KRTAP5-11 | c.469T>G p.*157Gext*37 | Nonstop Mutation (SNP) | VAF 62/85 reads (73%) | catalogued as COSV100651784; called by muse, mutect2, varscan2
- LAMB3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs761752478, COSV61916869; called by muse, mutect2, varscan2
- LIN7A | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.171); catalogued as COSV54021555; called by muse, mutect2, varscan2
- LRRC74A | c.1107C>T p.N369= | Splice Region (SNP) | VAF 12/27 reads (44%) | catalogued as rs748934451, COSV53609481; called by muse, mutect2, varscan2
- MAMDC4 | c.706T>A p.C236S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99915574; called by muse, mutect2
- MAT1A | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs200894913, COSV100944420; called by muse, mutect2, varscan2
- MCHR1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201438193, COSV50762069; called by muse, mutect2, varscan2
- MEFV | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs104895187, COSV54821000, COSV54826308; called by muse, mutect2, varscan2
- NFX1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100582021; called by muse, mutect2, varscan2
- NME8 | c.1763A>C p.N588T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV99553118; called by muse, mutect2, varscan2
- NRAP | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as COSV100748384; called by muse, mutect2, varscan2
- NRXN1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.53); catalogued as rs868375208, COSV68016558; called by muse, mutect2, varscan2
- NT5DC2 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as COSV100194753; called by muse, mutect2, varscan2
- OLFM3 | c.1431C>A p.D477E (on ENST00000338858 / NM_001288821.1; = p.D457E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV100129220; called by muse, varscan2
- OR11L1 | c.68G>T p.W23L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100869414; called by muse, mutect2, varscan2
- OR2Y1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57136162; called by muse, mutect2, varscan2
- OSBPL6 | c.2522T>A p.V841E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99507140; called by muse, mutect2, varscan2
- PCDH15 | c.2474C>A p.T825N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV100218898; called by muse, mutect2, varscan2
- PCOLCE2 | c.508T>A p.W170R | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99930555; called by muse, mutect2, varscan2
- PEG3 | c.2282A>C p.K761T | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55627288, COSV99688396; called by muse, mutect2, varscan2
- PKD1L2 | c.1499T>A p.F500Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.093); catalogued as COSV100449789; called by muse, mutect2, varscan2
- PRAMEF4 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99339695; called by muse, mutect2, varscan2
- PRPF6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99411809; called by muse, mutect2, varscan2
- PSAT1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100716560; called by muse, mutect2, varscan2
- PSG8 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100126104; called by muse, mutect2, varscan2
- PTPRT | c.3346G>A p.V1116M | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs761910971, COSV61973031; called by muse, mutect2, varscan2
- RFX2 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770125931, COSV100353682; called by muse, mutect2, varscan2
- RNF20 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100874315; called by muse, mutect2, varscan2
- RRAGD | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100784526; called by muse, mutect2, varscan2
- SACS | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV101207374; called by muse, mutect2, varscan2
- SCN2A | c.5914C>A p.P1972T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99331057; called by muse, mutect2, varscan2
- SHISAL1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 47/176 reads (27%) | catalogued as COSV66987723; called by muse, mutect2, varscan2
- SIPA1L1 | c.3521G>T p.G1174V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100665392; called by muse, mutect2, varscan2
- SLC9B1 | c.1468A>C p.I490L | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs764358661, COSV56472793, COSV99599453; called by muse, mutect2
- SLX4 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV99567879; called by muse, mutect2, varscan2
- SMARCC1 | c.584T>G p.F195C | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV99592614; called by muse, mutect2, varscan2
- SOHLH2 | c.388A>C p.S130R | Missense Mutation (SNP) | VAF 146/274 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV100499353; called by muse, mutect2, varscan2
- SOX9 | c.329A>C p.N110T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV99818056, COSV99818334; called by muse, mutect2, varscan2
- SP5 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1423962777, COSV100935257; called by muse, mutect2
- TECTA | c.5111G>A p.C1704Y | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99879464; called by muse, mutect2, varscan2
- TMEM132B | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs374760768; called by muse, mutect2, varscan2
- TMEM70 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV99513886; called by muse, mutect2, varscan2
- TRAF1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs368092786; called by muse, mutect2, varscan2
- TRPC1 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99858533; called by muse, mutect2, varscan2
- TRPS1 | c.3676G>A p.D1226N (on ENST00000220888 / NM_001330599.2; = p.D1239N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99629844; called by muse, mutect2, varscan2
- TSPYL5 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1389732110, COSV59072251; called by muse, mutect2, varscan2
- UBAP2L | c.3146A>T p.H1049L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99670976; called by muse, mutect2, varscan2
- UGT2B4 | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59319947, COSV59320070; called by muse, mutect2, varscan2
- VPS35L | c.2419G>T p.D807Y | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99220397; called by muse, mutect2, varscan2
- WDR36 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs1410152602, COSV101540789; called by muse, mutect2, varscan2
- YEATS2 | c.3772G>T p.D1258Y | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100527699; called by muse, mutect2, varscan2
- YTHDC2 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs771559761, COSV99363153; called by muse, mutect2, varscan2
- ZFP82 | c.1113T>G p.C371W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101089001; called by muse, mutect2, varscan2
- ZNF112 | c.1501G>A p.E501K (on ENST00000337401 / NM_001083335.2; = p.E495K on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1429222424, COSV100495658; called by muse, mutect2, varscan2
- ZNF236 | c.1889G>C p.G630A | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99470086; called by muse, mutect2, varscan2
- ZNF468 | c.1254A>C p.K418N | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99700470; called by muse, mutect2, varscan2
- ZNF479 | c.1410T>A p.C470* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100482670; called by muse, mutect2, varscan2
- ZNF569 | c.1862T>G p.L621R | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100386411; called by muse, mutect2, varscan2
- ZNF836 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375011741; called by muse, varscan2
- ZWINT | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100571502; called by muse, mutect2, varscan2
- BCL2L15 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2
- CCKAR | c.745_754del p.S249Kfs*54 | Frame Shift Del (DEL) | VAF 21/125 reads (17%) | called by mutect2, pindel, varscan2
- MUC2 | c.412G>C p.V138L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.37); called by muse, mutect2, varscan2
- OR4A5 | c.89del p.L30Yfs*6 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- OR4A5 | c.86T>A p.F29Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- SLIT3 | c.306_307del p.G103Rfs*17 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- UBC | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF133 | c.1101_1110del p.N368Pfs*195 (on ENST00000316358 / NM_001352454.2; = p.N367Pfs*195 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.17736T>C p.S5912= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV101315741; called by muse, mutect2, varscan2
- C12orf42 | c.354T>G p.S118= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV100172061; called by muse, mutect2, varscan2
- C22orf23 | c.231A>G p.Q77= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99317173; called by muse, mutect2, varscan2
- CHSY3 | c.2451T>G p.S817= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV100518872; called by muse, mutect2, varscan2
- CNGA2 | c.1290G>A p.K430= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs776787921, COSV100323539, COSV100323566; called by muse, mutect2, varscan2
- CSMD3 | c.10587C>T p.N3529= (on ENST00000297405 / NM_001363185.1; = p.N3360= on NM_052900.3) | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs753532523, COSV52165605; called by muse, mutect2, varscan2
- CSMD3 | c.9G>C p.G3= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs1209952027, COSV52206014, COSV99831132; called by muse, mutect2, varscan2
- DIRAS1 | c.492G>T p.L164= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100053007; called by muse, mutect2, varscan2
- DOK6 | c.762A>G p.P254= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV101234421; called by muse, mutect2, varscan2
- DPYSL4 | c.756C>A p.V252= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV100633906; called by muse, mutect2, varscan2
- GPAT2 | c.1167C>T p.V389= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs761873063, COSV100853257; called by muse, mutect2, varscan2
- KDF1 | c.864G>A p.L288= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100264441, COSV57671009; called by muse, mutect2, varscan2
- KLF10 | c.1101G>A p.R367= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV99574700; called by muse, mutect2, varscan2
- LIN7C | c.495A>G p.G165= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs942483861, COSV99536161; called by muse, mutect2, varscan2
- LPAR3 | c.666G>A p.P222= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs140283678; called by muse, mutect2, varscan2
- MDGA1 | c.1548G>C p.T516= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99776260, COSV99776706; called by muse, mutect2, varscan2
- MGAT5B | c.1218C>T p.Y406= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs752934490, COSV56926591; called by muse, mutect2, varscan2
- NNT | c.1806C>T p.A602= | Silent (SNP) | VAF 43/233 reads (18%) | catalogued as rs200162492, COSV99238710; called by muse, mutect2, varscan2
- NUP107 | c.765G>A p.A255= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs760015459, COSV57497026; called by muse, mutect2, varscan2
- NUP214 | c.5715G>A p.S1905= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs757729764, COSV63911621; called by muse, mutect2, varscan2
- OR8U1 | c.570A>G p.S190= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as COSV100163863; called by muse, mutect2, varscan2
- PLIN3 | c.390G>A p.S130= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs369609254; called by muse, mutect2, varscan2
- PLPP2 | c.537G>A p.L179= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99514604; called by muse, mutect2, varscan2
- PTPRD | c.5208T>C p.N1736= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100644202; called by muse, mutect2, varscan2
- RYR1 | c.774C>T p.L258= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV62102816; called by muse, mutect2, varscan2
- S1PR2 | c.111G>A p.S37= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as rs781176630, COSV100495300; called by muse, mutect2, varscan2
- SCN7A | c.4704T>C p.V1568= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV101313166; called by muse, mutect2, varscan2
- SEMA4C | c.198C>T p.Y66= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs1468761348, COSV100560862; called by muse, mutect2, varscan2
- SGSM2 | c.1935C>T p.L645= (on ENST00000426855 / NM_001098509.2; = p.L690= on NM_014853.3) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99280009; called by muse, mutect2, varscan2
- SLC35G5 | c.360T>C p.S120= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV99644166; called by muse, mutect2, varscan2
- SPATA5L1 | c.9G>A p.P3= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs566780658, COSV99972984; called by muse, mutect2, varscan2
- SPTBN4 | c.480C>T p.I160= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs576326506, COSV100150050, COSV58947707; called by muse, mutect2, varscan2
- SWT1 | c.2190G>A p.L730= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV100833212; called by muse, mutect2, varscan2
- TRPS1 | c.2361T>C p.D787= (on ENST00000220888 / NM_001330599.2; = p.D800= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/257 reads (25%) | catalogued as rs1433286880, COSV99629849; called by muse, mutect2, varscan2
- ZFHX3 | c.3732G>A p.T1244= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs373469033; called by muse, mutect2, varscan2
- ZNF385B | c.87G>A p.G29= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV101343074; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840611 C>T | 5'Flank (SNP) | VAF 9/65 reads (14%) | catalogued as rs751030899, COSV100006127; called by muse, mutect2, varscan2
- IGHV1-12 | n.142T>G | RNA (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- NPR3 | c.*3084T>C | 3'UTR (SNP) | VAF 25/117 reads (21%) | catalogued as COSV99422737; called by muse, mutect2, varscan2
- SNORD116-27 | n.45A>C | RNA (SNP) | VAF 31/38 reads (82%) | called by muse, mutect2, varscan2
